Somatic mutation profile of tumor specimen TARGET-10-PANVTB-09A (aliquot TARGET-10-PANVTB-09A-01D) from TARGET case TARGET-10-PANVTB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (868 days).
Specimen TARGET-10-PANVTB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85a5ba80-e7b6-468c-b737-14c80d6217d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVTB-10A (Blood Derived Normal), aliquot TARGET-10-PANVTB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7968b1-2409-4a7c-9846-1d7e6a293c1a

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CILP2 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs1191217649; called by mutect2, varscan2
- CNTN5 | c.2078C>A p.P693Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV54308039; called by muse, mutect2, varscan2
- DNM2 | c.2308C>T p.R770* (on ENST00000355667 / NM_001005360.3; = p.R766* on NM_004945.3) | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV53033391; called by mutect2, varscan2
- GPR37 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as rs780171990; called by muse, mutect2, varscan2
- IGF2R | c.2587G>A p.G863S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs776307638, COSV100808268; called by muse, mutect2, varscan2
- IL7R | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV57406053, COSV57408353; called by muse, mutect2, varscan2
- PTPRD | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs376714429; called by muse, mutect2, varscan2
- ZFHX3 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51717973, COSV51725973, COSV51733095; called by muse, mutect2, varscan2
- BARX2 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RXRB | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.6724_6725insC p.Y2242Sfs*82 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- EVPL | c.3096G>A p.A1032= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs139450563; called by muse, mutect2, varscan2
- FBXW8 | c.1050C>T p.D350= (on ENST00000309909; = p.D388= on NM_012174.1) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs770300279, COSV59298188; called by muse, mutect2, varscan2
- HCN4 | c.2304C>T p.T768= | Silent (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- HS2ST1 | c.114C>T p.R38= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs561647289; called by muse, mutect2, varscan2
- AC018755.3 | n.192C>T | RNA (SNP) | VAF 15/30 reads (50%) | catalogued as rs116910811; called by muse, mutect2, varscan2
- PSME2 | c.82-112C>T | Intron (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
